Somatic mutation profile of tumor specimen 98225215-ff21-4893-8b6d-d9b7e7 (aliquot 98225215-ff21-4893-8b6d-d9b7e7_D6_1) from CPTAC case 11BR012, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.3 years (28,226 days).
Specimen 98225215-ff21-4893-8b6d-d9b7e7: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32926bfb-9153-4b37-a923-5b5c7fa81117.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 5e62d006-cf7f-45e4-8b14-fcb7a0 (Blood Derived Normal), aliquot 5e62d006-cf7f-45e4-8b14-fcb7a0_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd374141-76cb-4ac3-a6a8-a8d04a121439

The open-access MAF lists 110 somatic variants for this specimen: 77 protein-altering or splice-affecting, 24 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 24, Intron 3, Splice Site 3, Nonsense Mutation 3, Frame Shift Del 2, 5'UTR 2, Frame Shift Ins 2, Splice Region 1, RNA 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM8 | c.1954G>A p.G652R | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as rs757636021; called by muse, mutect2, varscan2
- AFMID | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 113/736 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs771105807, COSV59975387; called by muse, mutect2, varscan2
- ATP2B2 | c.1167G>A p.A389= (on ENST00000352432; = p.A355= on NM_001683.5) | Splice Region (SNP) | VAF 21/350 reads (6%) | catalogued as rs201861535, COSV100659756, COSV100659932; called by muse, mutect2
- CACNA2D4 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.987); catalogued as rs766593449, COSV54947762; called by muse, mutect2, varscan2
- CERCAM | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs139025492, COSV65710836; called by muse, mutect2, varscan2
- CHD5 | c.2896C>T p.R966W | Missense Mutation (SNP) | VAF 68/119 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1557547572; called by muse, mutect2, varscan2
- CISH | c.617T>C p.V206A (on ENST00000348721 / NM_145071.4; = p.V223A on NM_013324.6) | Missense Mutation (SNP) | VAF 49/303 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs966907414; called by muse, mutect2, varscan2
- COL7A1 | c.5120G>A p.R1707Q | Missense Mutation (SNP) | VAF 22/275 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.377); catalogued as rs747945597, COSV60394783; called by muse, mutect2
- DCC | c.2635C>T p.R879* | Nonsense Mutation (SNP) | VAF 83/393 reads (21%) | catalogued as rs770131833, COSV59124491; called by muse, mutect2, varscan2
- DYNC2I1 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1292679110; called by muse, mutect2
- GAD2 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as rs772567180; called by muse, mutect2, varscan2
- GIMAP7 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs549466095; called by muse, mutect2, varscan2
- LCE1A | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 56/418 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs749443782, COSV100632109; called by muse, mutect2, varscan2
- LIPJ | c.204C>A p.N68K | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs761360353; called by muse, mutect2, varscan2
- MAGEE1 | c.2309G>A p.G770E | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.986); catalogued as COSV63909046; called by muse, mutect2, varscan2
- NLRP4 | c.2418C>G p.N806K | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV56719816; called by muse, mutect2, varscan2
- NUFIP2 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 47/301 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs545226025; called by muse, mutect2, varscan2
- OBSCN | c.13277C>T p.T4426M | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1351744113; called by muse, mutect2, varscan2
- OR52B2 | c.22A>G p.I8V | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1373546442; called by muse, mutect2, varscan2
- PFKL | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1325414241, COSV62464100; called by muse, mutect2
- PIGO | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 59/293 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs142276590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLAG1 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 72/271 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs748840607, COSV57609705; called by muse, mutect2, varscan2
- PPP1R3F | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.935); catalogued as COSV50017725; called by muse, varscan2
- PRDM9 | c.1638T>G p.H546Q | Missense Mutation (SNP) | VAF 33/806 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.535); catalogued as COSV57016098; called by muse, mutect2
- PTCD3 | c.309+2_309+3del p.X103_splice | Splice Site (DEL) | VAF 38/128 reads (30%) | catalogued as rs1190451451; called by pindel, varscan2
- PTK2 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.014); catalogued as rs879079754, COSV61783330; called by muse, mutect2, varscan2
- PTPRD | c.3739T>A p.S1247T | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.047); catalogued as COSV61932051; called by muse, mutect2, varscan2
- PTPRU | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 90/302 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs756818305, COSV60527278; called by mutect2, varscan2
- RAB38 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 19/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs114421655; called by muse, mutect2
- RTN4R | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 195/484 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs780355528; called by muse, mutect2, varscan2
- SLC12A3 | c.1629C>G p.I543M | Missense Mutation (SNP) | VAF 92/431 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52632180, COSV99344535; called by muse, mutect2, varscan2
- SLC1A1 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.86); catalogued as rs376500704; called by muse, mutect2, varscan2
- SP4 | c.1862G>C p.R621P | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV56023728; called by muse, mutect2, varscan2
- ST3GAL6 | c.355G>T p.V119L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs1181811463; called by muse, mutect2
- TRAPPC12 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 51/347 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.558); catalogued as rs746733215; called by muse, mutect2, varscan2
- TRAPPC8 | c.3505G>C p.A1169P | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.173); catalogued as rs745383278; called by muse, mutect2, varscan2
- TRAPPC8 | c.3105G>T p.W1035C | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1216691305, COSV51973817; called by muse, mutect2, varscan2
- UNC13B | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 58/308 reads (19%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.039); catalogued as rs765577061, COSV65939542; called by muse, mutect2, varscan2
- VN1R2 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 22/123 reads (18%) | PolyPhen probably damaging (0.956); catalogued as rs1257821984; called by muse, mutect2
- WARS1 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs780688625; called by muse, mutect2, varscan2
- ZNF831 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs558393472, COSV99057634; called by muse, mutect2, varscan2
- ADA2 | c.1094C>G p.T365S (on ENST00000262607; = p.T124S on NM_177405.3) | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- AKR1C1 | c.589T>C p.F197L | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASTN2 | c.1511A>G p.N504S (on ENST00000313400 / NM_001365069.1; = p.N453S on NM_014010.5) | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- BFSP1 | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 20/405 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); called by muse, mutect2
- BRDT | c.2518G>T p.A840S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- C9 | c.383T>A p.F128Y | Missense Mutation (SNP) | VAF 60/425 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC9B | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRNA3 | c.239T>A p.I80N | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DHX37 | c.1710C>A p.D570E | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DPP6 | c.706G>T p.E236* (on ENST00000377770 / NM_001364500.2; = p.E174* on NM_001936.5) | Nonsense Mutation (SNP) | VAF 71/184 reads (39%) | called by muse, mutect2, varscan2
- FHAD1 | c.3049G>C p.D1017H | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, varscan2
- GABRE | c.521T>C p.M174T | Missense Mutation (SNP) | VAF 104/429 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- GOLGB1 | c.599G>A p.S200N | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GPRC5C | c.194_195insCCCAC p.A66Pfs*91 (on ENST00000652232; = p.A21Pfs*91 on NM_018653.4) | Frame Shift Ins (INS) | VAF 25/149 reads (17%) | called by mutect2, pindel, varscan2
- HMCN1 | c.6137T>C p.L2046S | Missense Mutation (SNP) | VAF 114/505 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HMGN5 | c.15+1G>A p.X5_splice | Splice Site (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2
- IFFO2 | c.913_920del p.C305Rfs*23 | Frame Shift Del (DEL) | VAF 40/222 reads (18%) | called by mutect2, pindel, varscan2
- IRGM | c.169A>T p.N57Y | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated, low confidence (0.05); called by muse, mutect2
- KDR | c.2806G>A p.V936I | Missense Mutation (SNP) | VAF 98/304 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LRRTM1 | c.1458G>T p.Q486H | Missense Mutation (SNP) | VAF 65/445 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- MACIR | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 94/520 reads (18%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MARS2 | c.479T>A p.L160H | Missense Mutation (SNP) | VAF 58/312 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ORC3 | c.1963G>C p.V655L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- PARD6B | c.676A>G p.K226E | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH11X | c.3625C>T p.H1209Y | Missense Mutation (SNP) | VAF 257/695 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- RNF213 | c.1766dup p.Y589* | Nonsense Mutation (INS) | VAF 76/470 reads (16%) | called by mutect2, pindel, varscan2
- RNF222 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- RTL4 | c.414dup p.P139Tfs*13 | Frame Shift Ins (INS) | VAF 148/440 reads (34%) | called by mutect2, pindel, varscan2
- SLC27A5 | c.1420G>T p.A474S | Missense Mutation (SNP) | VAF 45/307 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SSPOP | n.10341+1G>T | Splice Site (SNP) | VAF 116/264 reads (44%) | called by muse, mutect2, varscan2
- STARD9 | c.13635_13639delinsTTCC p.G4546Sfs*36 | Frame Shift Del (DEL) | VAF 66/354 reads (19%) | called by pindel, varscan2*
- STAT1 | c.1631A>T p.K544M | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SYNE1 | c.1571A>G p.K524R (on ENST00000367255 / NM_182961.4; = p.K531R on NM_033071.3) | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYT6 | c.351C>A p.D117E (on ENST00000610222 / NM_001366225.1; = p.D32E on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRGC2 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ZFP28 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.018); called by muse, mutect2
- ACCS | c.1131C>T p.Y377= | Silent (SNP) | VAF 38/225 reads (17%) | called by muse, mutect2, varscan2
- ACTA2 | c.1059C>T p.T353= | Silent (SNP) | VAF 26/568 reads (5%) | called by muse, mutect2
- ADAMTS10 | c.2004G>A p.T668= | Silent (SNP) | VAF 97/373 reads (26%) | catalogued as rs376367684, COSV104373580; called by muse, mutect2, varscan2
- BAG6 | c.30T>A p.A10= | Silent (SNP) | VAF 60/147 reads (41%) | called by muse, mutect2, varscan2
- CLEC9A | c.6C>T p.H2= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs756415045; called by muse, mutect2, varscan2
- COL18A1 | c.3894C>T p.G1298= (on ENST00000359759 / NM_130444.3; = p.G1063= on NM_030582.4) | Silent (SNP) | VAF 84/380 reads (22%) | catalogued as rs369139821; called by muse, mutect2, varscan2
- GGCX | c.2166T>C p.Y722= | Silent (SNP) | VAF 42/229 reads (18%) | catalogued as rs200997067; called by muse, mutect2, varscan2
- HRNR | c.888C>T p.H296= | Silent (SNP) | VAF 115/754 reads (15%) | catalogued as rs142350682; called by muse, mutect2, varscan2
- IGHE | c.837C>T p.T279= | Silent (SNP) | VAF 95/455 reads (21%) | catalogued as rs782328064; called by muse, mutect2, varscan2
- IRAK2 | c.1467G>A p.L489= | Silent (SNP) | VAF 91/205 reads (44%) | catalogued as rs745896838; called by muse, mutect2, varscan2
- LENG9 | c.1347G>C p.V449= | Silent (SNP) | VAF 22/171 reads (13%) | called by muse, mutect2, varscan2
- MAP3K3 | c.1006C>A p.R336= | Silent (SNP) | VAF 29/422 reads (7%) | called by muse, mutect2
- MAP7D1 | c.1698G>A p.E566= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs1275374414; called by muse, mutect2, varscan2
- MED6 | c.528T>G p.R176= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- MUC4 | c.12819C>T p.D4273= (on ENST00000463781 / NM_018406.7; = p.D37= on NM_004532.6) | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs766537013, COSV57782780; called by muse, mutect2, varscan2
- NTRK1 | c.1227G>A p.E409= | Silent (SNP) | VAF 138/406 reads (34%) | catalogued as COSV62328374; called by muse, mutect2, varscan2
- NUP153 | c.2055A>G p.K685= | Silent (SNP) | VAF 61/320 reads (19%) | called by muse, mutect2, varscan2
- OR4D9 | c.171G>A p.T57= | Silent (SNP) | VAF 90/270 reads (33%) | catalogued as rs1451512271, COSV61435763; called by muse, mutect2, varscan2
- OR5AS1 | c.564A>T p.S188= | Silent (SNP) | VAF 38/689 reads (6%) | called by muse, mutect2
- PIEZO2 | c.6000G>A p.P2000= | Silent (SNP) | VAF 62/145 reads (43%) | catalogued as rs1454107934; called by muse, mutect2, varscan2
- STS | c.42C>G p.A14= | Silent (SNP) | VAF 40/694 reads (6%) | called by muse, mutect2
- UGGT1 | c.1146A>G p.G382= | Silent (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- USP47 | c.2244G>A p.L748= (on ENST00000399455 / NM_001372095.1; = p.L660= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 95/310 reads (31%) | called by muse, varscan2
- XKR9 | c.849C>G p.T283= | Silent (SNP) | VAF 18/356 reads (5%) | catalogued as COSV68773063; called by muse, mutect2
- C11orf96 | chr11:43943314 G>A | 3'Flank (SNP) | VAF 6/18 reads (33%) | called by muse, varscan2
- CDC25C | c.369+29G>C | Intron (SNP) | VAF 20/113 reads (18%) | called by muse, mutect2, varscan2
- COX15 | c.-45C>A | 5'UTR (SNP) | VAF 59/186 reads (32%) | called by muse, mutect2, varscan2
- EPB41L1 | c.1669-2670G>A | Intron (SNP) | VAF 20/347 reads (6%) | catalogued as rs1378382083; called by muse, mutect2
- NIM1K | c.-2C>T | 5'UTR (SNP) | VAF 17/57 reads (30%) | catalogued as rs750944615, COSV58140899; called by muse, mutect2, varscan2
- OR52A4P | n.686G>T | RNA (SNP) | VAF 47/95 reads (49%) | called by muse, mutect2, varscan2
- PLCH2 | c.2959+16C>T | Intron (SNP) | VAF 8/92 reads (9%) | catalogued as rs1481896311; called by muse, mutect2
- RNA5-8SP2 | chr16:34158814 G>A | 5'Flank (SNP) | VAF 13/41 reads (32%) | catalogued as rs756684681; called by muse, mutect2, varscan2
- SLC14A1 | c.*30G>A | 3'UTR (SNP) | VAF 53/268 reads (20%) | catalogued as rs535711192; called by muse, mutect2, varscan2
